Somatic mutation profile of tumor specimen TCGA-BB-A5HU-01A (aliquot TCGA-BB-A5HU-01A-11D-A28R-08) from TCGA case TCGA-BB-A5HU, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.9 years (17,502 days).
Specimen TCGA-BB-A5HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eb26fe7-a265-461e-a127-a440305b65a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-A5HU-10A (Blood Derived Normal), aliquot TCGA-BB-A5HU-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a261cb6-cf23-4db1-b882-dedfc1893883

The open-access MAF lists 194 somatic variants for this specimen: 137 protein-altering or splice-affecting, 54 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 54, Nonsense Mutation 13, RNA 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 28/61 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2315C>G p.S772C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.51); catalogued as COSV101329949; called by muse, mutect2
- ACACB | c.4730A>T p.E1577V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100622435; called by muse, mutect2, varscan2
- ACSS3 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs142377880, COSV99698934; called by muse, mutect2, varscan2
- ADAMTS3 | c.2623A>G p.K875E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV99710389; called by muse, mutect2, varscan2
- ADCY8 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53903301, COSV99651047; called by muse, mutect2, varscan2
- ADGRL3 | c.434G>A p.R145Q (on ENST00000506720 / NM_001322402.2; = p.R77Q on NM_015236.6) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.069); catalogued as rs184034371, COSV72269498; called by muse, mutect2, varscan2
- ALOX5 | c.1996G>C p.D666H | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.203); catalogued as COSV100979982; called by muse, mutect2, varscan2
- ANKRD50 | c.4006C>G p.Q1336E | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV101538894, COSV72384969; called by muse, mutect2, varscan2
- ARMC6 | c.1021C>T p.Q341* (on ENST00000392336; = p.Q316* on NM_033415.4) | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99522948; called by muse, varscan2
- ATF7 | c.1318C>T p.Q440* (on ENST00000548446 / NM_001366555.2; = p.Q429* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100129206; called by muse, mutect2, varscan2
- ATF7IP2 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV100202528; called by muse, mutect2
- ATP6V1F | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as rs1237319096, COSV99925852; called by muse, mutect2, varscan2
- ATRNL1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV100744408; called by muse, mutect2, varscan2
- BEGAIN | c.1242G>C p.M414I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100766919; called by muse, mutect2
- CACNA2D1 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as COSV100666161, COSV100667868; called by muse, mutect2, varscan2
- CADM2 | c.199G>C p.D67H (on ENST00000407528 / NM_001167674.2; = p.D69H on NM_153184.4) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV101053194; called by muse, mutect2, varscan2
- CAPN2 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54335364, COSV54339385; called by muse, mutect2, varscan2
- CCDC138 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99718811; called by muse, mutect2, varscan2
- CDCP1 | c.2485C>G p.Q829E | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV56105631; called by muse, mutect2, varscan2
- CEP350 | c.5374C>A p.Q1792K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.317); catalogued as COSV100854351; called by muse, mutect2
- CHRM5 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367778274, COSV101271858; called by muse, mutect2, varscan2
- CIC | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50567843, COSV50651034; called by muse, mutect2, varscan2
- CLUAP1 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.623); catalogued as COSV100489535; called by muse, mutect2, varscan2
- CMA1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as rs376938676; called by muse, mutect2, varscan2
- COL24A1 | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100992986; called by muse, mutect2, varscan2
- CRYGS | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV100329912; called by muse, mutect2, varscan2
- CSMD3 | c.2564C>A p.S855* (on ENST00000297405 / NM_001363185.1; = p.S751* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as COSV99827036; called by muse, mutect2, varscan2
- DAAM1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100658195; called by muse, mutect2, varscan2
- DYNC1H1 | c.8590G>C p.E2864Q | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100794570; called by muse, mutect2, varscan2
- EXD3 | c.2507G>T p.G836V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100573479; called by muse, mutect2, varscan2
- FAM135B | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52713418, COSV99420074; called by muse, mutect2
- FAM234A | c.810G>C p.R270S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.365); catalogued as rs766221503, COSV100055505; called by muse, mutect2, varscan2
- FBH1 | c.584C>G p.S195* (on ENST00000362091 / NM_178150.3; = p.S246* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100758632; called by muse, mutect2, varscan2
- FRY | c.7951G>A p.G2651R | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV100968859; called by muse, mutect2, varscan2
- GALNTL5 | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV101217717; called by muse, mutect2, varscan2
- GDNF | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100427366; called by muse, mutect2, varscan2
- GNB3 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99300931; called by muse, mutect2, varscan2
- GOPC | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as COSV99270727; called by muse, mutect2, varscan2
- GRIN2A | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs560057284, COSV58020945, COSV58030818; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- HEG1 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200253057; called by muse, mutect2, varscan2
- HELZ | c.5121C>A p.H1707Q | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.165); catalogued as COSV100698544; called by muse, mutect2, varscan2
- HSPA1L | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100989337; called by muse, mutect2
- ITGA8 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100958952; called by muse, mutect2, varscan2
- ITGB4 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.178); catalogued as rs751452707, COSV52323734; called by muse, mutect2, varscan2
- ITSN2 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.033); catalogued as COSV61949739; called by muse, mutect2, varscan2
- KAT6B | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as COSV54744272, COSV99767459; called by muse, mutect2
- KCNK15 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV100865086; called by muse, mutect2, varscan2
- KIAA0100 | c.2533C>T p.Q845* | Nonsense Mutation (SNP) | VAF 46/254 reads (18%) | catalogued as COSV101197228; called by muse, mutect2, varscan2
- KRT12 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs368116028; called by muse, mutect2, varscan2
- KRT83 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs149581248; ClinVar: likely benign; called by muse, mutect2, varscan2
- L3MBTL4 | c.560C>G p.P187R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as COSV99527716; called by muse, mutect2, varscan2
- LAMA1 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs1042493103, COSV101055330; called by muse, mutect2, varscan2
- LAMC1 | c.2208G>C p.E736D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV99279115; called by muse, mutect2, varscan2
- LGI4 | c.1581C>G p.I527M | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV59532879, COSV59535344; called by muse, mutect2, varscan2
- LRP6 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 13/121 reads (11%) | catalogued as COSV99742602; called by muse, mutect2, varscan2
- LRRC36 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1175910247, COSV99338465; called by muse, mutect2, varscan2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2
- LRRFIP1 | c.1847G>A p.R616K (on ENST00000392000 / NM_001137552.2; = p.R592K on NM_004735.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99790460; called by muse, mutect2, varscan2
- MADD | c.2864G>A p.G955D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100211127; called by muse, mutect2, varscan2
- MAPKBP1 | c.4171G>A p.E1391K (on ENST00000456763 / NM_001128608.2; = p.E1385K on NM_014994.3) | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.661); catalogued as COSV52963710, COSV99529030; called by muse, mutect2
- MAST1 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs373621251; called by muse, mutect2
- MFNG | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as COSV99324702; called by muse, mutect2, varscan2
- MLKL | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV100087228; called by muse, mutect2, varscan2
- MMP14 | c.1400T>A p.F467Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100313963; called by muse, mutect2, varscan2
- MYT1L | c.2759C>G p.S920C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101219204; called by muse, mutect2, varscan2
- NAA15 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99649338; called by muse, mutect2, varscan2
- NAV3 | c.4585C>G p.R1529G | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99887662, COSV99893472; called by muse, mutect2, varscan2
- NAV3 | c.6701C>G p.S2234C (on ENST00000397909 / NM_001024383.2; = p.S2212C on NM_014903.6) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99887666; called by muse, mutect2, varscan2
- NCAPH2 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs956591417, COSV100237970; called by muse, mutect2, varscan2
- NCOA1 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99945372; called by muse, mutect2, varscan2
- NLRP3 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100275410; called by muse, mutect2
- NYNRIN | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV101230509, COSV101230522; called by muse, mutect2, varscan2
- OR2A2 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101286622, COSV68872689; called by muse, mutect2
- OR2M3 | c.903C>G p.F301L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101513401, COSV71759046; called by muse, mutect2, varscan2
- OR5H6 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.003); catalogued as COSV101051746; called by muse, mutect2, varscan2
- P3H2 | c.1868C>T p.T623I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100077156; called by muse, mutect2, varscan2
- PCDH9 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100118849, COSV100124531; called by muse, mutect2, varscan2
- PCDHA13 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV56481525; called by muse, mutect2, varscan2
- PCDHGA2 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.052); catalogued as rs758237668, COSV53967119; called by muse, mutect2, varscan2
- PCDHGB7 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99532592; called by muse, mutect2, varscan2
- PCLO | c.3401C>A p.A1134E | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as COSV100428273, COSV61612573; called by muse, mutect2, varscan2
- PHIP | c.5318G>A p.R1773Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs775492637, COSV51504491; called by muse, mutect2, varscan2
- PHIP | c.4285C>G p.L1429V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as rs768363637, COSV99243534; called by muse, mutect2, varscan2
- PIK3C2G | c.3211G>C p.G1071R (on ENST00000676171; = p.G1030R on NM_004570.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849995; called by muse, mutect2
- PKN3 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV99403340; called by muse, mutect2, varscan2
- PLCB2 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV99541646; called by muse, mutect2
- PNPLA1 | c.1204C>T p.Q402* (on ENST00000394571 / NM_001374623.1; = p.Q307* on NM_173676.2) | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV100462744; called by muse, mutect2, varscan2
- PRKDC | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV58060902; called by muse, mutect2
- PRPF40B | c.2216C>T p.S739L (on ENST00000380281; = p.S726L on NM_012272.3) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs1281603412, COSV99029419; called by muse, mutect2, varscan2
- PRSS38 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs762722703, COSV100816358; called by muse, mutect2, varscan2
- PTK2B | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs370030419; called by muse, mutect2, varscan2
- RASGRF1 | c.2865G>C p.L955F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV101174381; called by muse, mutect2, varscan2
- RAVER1 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99348911; called by muse, mutect2, varscan2
- RBM12 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100467119, COSV99048080; called by muse, mutect2, varscan2
- RDH11 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV101191380; called by muse, mutect2, varscan2
- RFFL | c.1047C>G p.I349M | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV99265187; called by muse, mutect2, varscan2
- RGS4 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 59/496 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV100905514, COSV100905524, COSV63358320; called by muse, mutect2, varscan2
- RIMBP2 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1177409370, COSV55470357; called by muse, mutect2, varscan2
- RNASE9 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100141129; called by muse, mutect2
- RNF216 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV101111269; called by muse, mutect2, varscan2
- RYR2 | c.8843G>A p.R2948K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as rs1159764894, COSV100768516; called by muse, mutect2
- SERPINA10 | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100003661; called by muse, mutect2, varscan2
- SIM1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs375766542, COSV53489181, COSV53493373; called by muse, mutect2, varscan2
- SIPA1 | c.2924C>G p.S975* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100425750; called by muse, mutect2
- SKI | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101049252, COSV66012872; called by muse, mutect2, varscan2
- SLIT2 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as COSV99881620; called by muse, mutect2
- SLIT3 | c.3097G>C p.E1033Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.073); catalogued as COSV100265764, COSV100268135; called by muse, mutect2, varscan2
- SPATA2L | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs1271711854, COSV99232121; called by muse, mutect2, varscan2
- SSBP2 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV100283134; called by muse, mutect2, varscan2
- SYNE2 | c.14162G>A p.G4721E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as COSV100646927; called by muse, mutect2, varscan2
- TACC2 | c.6184C>T p.Q2062* (on ENST00000334433; = p.Q140* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as COSV99586702; called by muse, mutect2, varscan2
- TGM4 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV99942171; called by muse, mutect2, varscan2
- THBS2 | c.2800G>C p.D934H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100827661; called by muse, mutect2, varscan2
- TIE1 | c.290C>G p.S97W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100992015; called by muse, mutect2, varscan2
- TMEM51 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV101051486, COSV65690951; called by muse, mutect2, varscan2
- TPR | c.3071G>A p.R1024K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766300100, COSV100823685; called by muse, mutect2, varscan2
- TTN | c.72778G>A p.D24260N (on ENST00000591111; = p.D16836N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | PolyPhen probably damaging (0.964); catalogued as COSV100598144; called by mutect2, varscan2
- TTN | c.45103G>C p.E15035Q (on ENST00000591111; = p.E7611Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | PolyPhen probably damaging (0.997); catalogued as COSV100598148; called by muse, mutect2, varscan2
- UBR3 | c.5614C>G p.H1872D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99773397; called by muse, mutect2, varscan2
- UBR4 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 37/130 reads (28%) | catalogued as COSV100920418; called by muse, mutect2, varscan2
- VPS18 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV99592318, COSV99592383; called by muse, mutect2, varscan2
- VSIG10 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs543565996, COSV63653463; called by muse, mutect2, varscan2
- WARS1 | c.1380C>G p.F460L | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100690045; called by muse, mutect2, varscan2
- WDR1 | c.402T>G p.D134E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.265); catalogued as COSV99306048; called by muse, mutect2, varscan2
- XIRP2 | c.678C>G p.F226L (on ENST00000628543; = p.F401L on NM_152381.6) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54681208, COSV99739318; called by muse, mutect2, varscan2
- YIPF7 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764265212, COSV100274365; called by muse, mutect2, varscan2
- ZBTB49 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as COSV100552376, COSV61925049; called by muse, mutect2, varscan2
- ZDBF2 | c.4705G>C p.D1569H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as rs1181517907, COSV100984430; called by muse, mutect2, varscan2
- ZFHX4 | c.5533G>C p.D1845H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV51488648; called by muse, mutect2
- ZKSCAN4 | c.1627C>G p.L543V | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV101043378; called by muse, mutect2, varscan2
- ZNF184 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV99279427; called by muse, mutect2, varscan2
- ZNF213 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101205943; called by muse, mutect2, varscan2
- ZNF613 | c.1432C>G p.H478D (on ENST00000293471 / NM_001031721.4; = p.H442D on NM_024840.4) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53272132, COSV99522853; called by muse, mutect2, varscan2
- ZNF829 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as COSV100451195, COSV61743295; called by muse, mutect2
- ANGPT1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUTM2D | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- AGAP3 | c.927C>T p.I309= (on ENST00000622464; = p.I345= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV58995253; called by muse, mutect2, varscan2
- APOB | c.7110G>A p.L2370= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs755657242, COSV99264036; ClinVar: likely benign; called by muse, mutect2, varscan2
- BBS10 | c.912G>A p.Q304= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as CD064496, COSV99674610; called by muse, mutect2
- CAPZB | c.267G>A p.P89= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs372623313; called by muse, mutect2, varscan2
- CASP3 | c.669G>A p.L223= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100394918; called by muse, mutect2, varscan2
- CCR8 | c.264C>T p.F88= | Silent (SNP) | VAF 32/191 reads (17%) | catalogued as COSV100413025; called by muse, mutect2, varscan2
- CIDEA | c.549G>A p.V183= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as COSV100254923; called by muse, mutect2, varscan2
- CIP2A | c.1851G>A p.V617= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99842680; called by muse, mutect2
- CNKSR1 | c.1050G>A p.L350= (on ENST00000374253 / NM_001297647.2; = p.L343= on NM_006314.3) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100836691; called by muse, mutect2, varscan2
- CRYBB1 | c.606C>T p.R202= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs769288122, COSV99315863; called by muse, mutect2, varscan2
- CT55 | c.498A>G p.A166= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99358801; called by muse, mutect2, varscan2
- DRC7 | c.1791G>A p.A597= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1486554585, COSV100395409; called by muse, mutect2, varscan2
- ERBB2 | c.936C>G p.T312= | Silent (SNP) | VAF 36/274 reads (13%) | catalogued as COSV99506961; called by muse, mutect2, varscan2
- FAT4 | c.13755C>T p.I4585= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100629211, COSV58691432; called by muse, mutect2, varscan2
- FRYL | c.5373G>T p.V1791= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99976081; called by muse, mutect2, varscan2
- GLB1L | c.1482G>A p.L494= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99850308; called by muse, mutect2, varscan2
- INAVA | c.297C>T p.I99= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as COSV100949890; called by muse, mutect2, varscan2
- ISY1 | c.588G>T p.R196= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99860649; called by muse, mutect2, varscan2
- KAT14 | c.1386C>T p.P462= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs767961876; called by muse, mutect2, varscan2
- KCTD12 | c.192C>T p.F64= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100499653; called by muse, mutect2, varscan2
- KIF7 | c.3621G>C p.L1207= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV99176063; called by muse, mutect2, varscan2
- MATN4 | c.345G>C p.L115= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100636910; called by muse, mutect2
- MEF2C | c.552T>A p.P184= | Silent (SNP) | VAF 44/276 reads (16%) | catalogued as rs952708610, COSV100424740; called by muse, mutect2, varscan2
- MIS18BP1 | c.2970C>T p.F990= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100172734; called by muse, mutect2, varscan2
- MLLT10 | c.810T>C p.T270= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1425167505; called by muse, mutect2
- MYO7B | c.2238C>T p.F746= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV67350994; called by muse, mutect2, varscan2
- NBEA | c.8013C>T p.L2671= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1362127662, COSV100082447, COSV59822886; called by muse, mutect2
- NRCAM | c.171T>C p.I57= (on ENST00000379028 / NM_001371124.1; = p.I51= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100694318; called by muse, mutect2, varscan2
- OR1S1 | c.120C>G p.L40= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as COSV100515264; called by muse, mutect2, varscan2
- PCDHB6 | c.2193A>G p.P731= | Silent (SNP) | VAF 21/247 reads (9%) | catalogued as COSV99169955; called by muse, mutect2
- PCDHGB2 | c.801C>T p.T267= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99532591, COSV99548982; called by muse, mutect2
- PLPPR2 | c.894C>G p.L298= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1333373719, COSV52260496, COSV99264256; called by muse, mutect2, varscan2
- PRB1 | c.750T>G p.P250= | Silent (SNP) | VAF 37/386 reads (10%) | catalogued as COSV53702693, COSV99555979; called by muse, mutect2
- PRR15L | c.276C>G p.L92= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99846464; called by muse, mutect2
- RGMA | c.1284G>A p.L428= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1378983858, COSV100224192; called by muse, mutect2
- RNF148 | c.73C>T p.L25= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100411467, COSV57385384; called by muse, mutect2, varscan2
- SCN4A | c.3675C>G p.V1225= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as COSV101438345; called by muse, mutect2, varscan2
- SLC7A14 | c.651C>G p.L217= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV99200385; called by muse, mutect2, varscan2
- SLK | c.3474G>A p.E1158= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100211540; called by muse, mutect2
- SPTLC1 | c.1419C>G p.L473= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99364575; called by muse, mutect2, varscan2
- SRCAP | c.7593A>C p.P2531= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as COSV99349485; called by muse, mutect2
- SYT11 | c.63C>T p.I21= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV64173893; called by muse, mutect2, varscan2
- TBC1D10B | c.1839G>A p.E613= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99976983; called by muse, mutect2, varscan2
- TMEM129 | c.627C>T p.L209= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1214081318, COSV100304945; called by muse, mutect2
- TP53 | c.528C>T p.C176= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV52687391, COSV52701599, COSV52735850, COSV99377692; called by muse, mutect2, varscan2
- TREML2 | c.870G>A p.K290= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101530143; called by muse, mutect2
- TRPS1 | c.639A>C p.A213= (on ENST00000220888 / NM_001330599.2; = p.A226= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/252 reads (10%) | catalogued as COSV99628930; called by muse, mutect2
- VCAN | c.9057C>T p.I3019= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV99424916; called by muse, mutect2, varscan2
- ZFHX4 | c.5787G>A p.Q1929= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99257834; called by muse, mutect2, varscan2
- ZMIZ1 | c.3203G>A p.*1068= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as COSV100565936; called by muse, mutect2, varscan2
- ZNF280A | c.978G>A p.R326= | Silent (SNP) | VAF 65/205 reads (32%) | catalogued as COSV100130974; called by muse, mutect2, varscan2
- ZNF454 | c.9C>G p.V3= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100194671, COSV100195181; called by muse, mutect2, varscan2
- ZNF622 | c.525G>A p.E175= | Silent (SNP) | VAF 52/193 reads (27%) | catalogued as COSV100432995, COSV58073542; called by muse, varscan2
- ZNF878 | c.1128C>T p.F376= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV101521182; called by muse, mutect2, varscan2
- ANKMY1 | c.-84G>A | 5'UTR (SNP) | VAF 37/133 reads (28%) | catalogued as COSV99801457; called by muse, mutect2, varscan2
- EIF4G1 | c.-91-65A>G | Intron (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100071544; called by muse, mutect2, varscan2
- RPS26P15 | n.117C>G | RNA (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
